Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A2RM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A2RM-01A (Primary Tumor).

[page 1 of 4]
Lab Results : Single Panel :

DOB	Sex	Race	MRN(s)

1CD-0-3
carcinoma, squamous cell, NOS 8070/3
Site: cervix, NOS C53.9 w 9/8/11

Panel: Surgical Pathology Report
Date:

- Abnormal Flags key: C Critical H High L Low R Review * Abnormal
- Interpretation Codes: (S) Susceptible (R) Resistant (MS) Moderately Susceptible (I) Intermediate
- Status codes: P-Preliminary F-Final C-Corrected I-In progress/incomplete X-Cancelled
- Dates and times displayed below are collection dates; to see the observation date and time for a result, hold your course over the collection time. Times are on a 24-hour clock.
- An asterisk [*] in the Note column or next to a panel name indicates a note is present. To view it, rest your mouse cursor on the [*].

Panel	Accession #	Sts Test	Collected	Value	Units	Range
Surgical Pathology Report		F				
Collection D/T:						
Obsv D/T						

Surgical Pathology Report

- Final Diagnosis
1. Right aortic node, excision:
Two lymph nodes, no tumor seen (0/2).
2. Left pelvic node, excision:
Eighteen lymph nodes, no tumor seen (0/18).
3. Right pelvic node, excision:
Sixteen lymph nodes, no tumor seen (0/16).
4. Portion of right parametrium, excision:
Portion of large blood vessel and associated fibroadipose tissue; no tumor seen.
5. Portion of left parametrium, excision:
Fibroadipose tissue; no tumor seen.
6. Uterus, tubes and ovaries, parametrium of upper vagina, 233.3g,
hysterectomy and bilateral salpingoophorectomy:
A. Invasive squamous cell carcinoma, poorly differentiated, 4.5 cm in maximum dimension, invasive to a depth of approximately 1.1 cm out of 2.0 cm of cervical wall, serosa not involved.
B. Parametrial margins negative for carcinoma
C. Vaginal cuff margins negative for carcinoma
D. Lymphovascular invasion present
E. Bilateral ovaries with benign follicular cysts.
F. Bilateral fallopian tubes with no specific pathologic change.
7. Left uterine artery
Sections of artery and associated fibroadipose tissue; no tumor seen.

The case material was reviewed and the report verified by:

[page 2 of 4]
Verification Date:

Pathologist(s)

Frozen Section Diagnosis

1A: Lymph nodes, no tumor seen. Reported to

Gross Description

The case is received in seven containers, each with the patient's name and medical record number.

Specimen 1 is designated "right aortic node" and is received fresh for frozen section and is described then as one piece of red-tan soft tissue measuring 2.5 x 2.0 x 1 cm and dissected to reveal multiple potential lymph nodes frozen in toto as 1A. The remaining specimen is now received following formalin fixation and is submitted as 1A in toto.

Specimen 2 is received fresh and is labeled "left pelvic node". The specimen consists of multiple fragments of yellow-tan soft tissue measuring 6.1 x 4.1 x 1.2 cm in aggregate. Further dissection reveals six potential lymph nodes, as large as 1.2 cm, which are dissected and submitted in 2A-C, remaining fat in 2D and 2E.

Specimen 3 is received fresh and is labeled "right pelvic node". The specimen consists of multiple fragments of tan fatty soft tissue measuring 5.8 x 3.7 x 1.4 cm aggregate. The specimen contains multiple potential lymph nodes as large as 0.9 cm, and are submitted in 3A through 3D.

Specimen 4 is received fresh and is labeled "portion of right parametrium". The specimen consists of one portion of tan soft tissue measuring 1.2 x 0.9 x 0.2 cm and is submitted in toto in 4A.

Specimen 5 is received fresh and is labeled portion of left parametrium. The specimen consists one portion of tan soft tissue measuring 1.6 x 0.8 x 0.3 cm, and is submitted in toto in 5A.

Specimen 6 is received fresh and is labeled "uterus, tubes and ovaries, parametrium of upper vagina". The specimen weighs 233.3 grams in toto. The uterus measures 7.9 cm superior to inferior, 7.1 cm cornu to cornu, and 3.5 cm anterior to posterior, and measures 3 cm in length, 4.6 cm lateral to lateral, and 4.4 cm anterior to posterior. The cervix is notable for a protruding friable red-tan mass appearing to be a posterior lesion. The

[page 3 of 4]
specimen also contains a cuff of vagina measuring from 1.2 to 2.7 cm, and grossly free of tumor. The serosa of the uterus and cervix is smooth and glistening. The uterus and cervix are bivalved along the anterior-posterior border to reveal the following: An endocervical canal 4.0 long, 0.4 cm is wide, an unremarkable endometrial cavity 4.6 cm long, and 3.9 cm wide, and 0.1 cm thick, and a myometrium notable for a thickness of 1.4 cm. The specimen is inked as following: Black is anterior, green is posterior, and the vaginal cuff is inked blue. The posterior ectocervix is replaced by a fungating mass lesion measuring 4.5 cm lateral to lateral and 2.9 cm anterior to posterior x 2.6 cm superior to inferior, with a tan-white surface. The mass lesion is located approximately 1 cm from the lower uterine segment posteriorly, and 1.5 cm from the anterior uterine segment. The mass is located 1.5 cm from the closest vaginal margin. Right and left parametria are shaved. They are grossly uninvolved by tumor. The left parametrial are submitted in toto in 6A through D, and the right parametrial is submitted in 6E through 6H. The vaginal cuff is submitted as follows: Left anterior cuff in 6I, right anterior cuff and 6J, and left posterior cuff in 6 K and right posterior cuff in 6L. An uninvolved

portion of vaginal cuff is cut off. The cervix is then processed as a cone, and submitted as follows: 2:00 as 6M, 12:30 as 6N, 1:00 as 6O, 2:00 as 6P, 2:30 6Q, 3:00 as 6R, 3:30 as 6S, 4:00 as 6T, 4:30 in 6U and 6V, 5:00 in 6W and 6X, 6:00 in 6Y and 6Z and 7:00 as 6AA and 6BB, 8:00 as 6CC, 8:30 as 6DD, 9:00 as 6EE, 9:30 as 6FF, 10:00 as 6GG, and 11:00 as 6HH. A section through anterior endocervix and lower uterine segment is submitted in 6II, and a section through posterior endocervix and lower uterine segment is submitted in 6JJ. A full thickness cross-section through anterior endometrium and myometrium is submitted in 6KK and a full thickness cross section through posterior endometrium myometrium is 6LL. The right ovary measures 4.0 x 2.8 x 1.8 cm and the right fallopian tube measures 3.3 cm x 0.3 cm in greatest dimension. Upon sectioning, the right ovary is multicystic and hemorrhagic with the cysts as large as 1.5 cm in diameter. Section through right ovary and adjacent fallopian tube is submitted in 6MM and representative sections of the right fallopian tube which looks grossly unremarkable is submitted in 6NN. The left ovary measures 3.7 x 2.9 x 1.2 cm and the left fallopian tube measures 3.6 cm x 0.3 cm in greatest diameter. Upon sectioning, the left ovary is cystic and has a cyst as large as 0.6 cm. A representative section of ovary with adjacent fallopian tube

[page 4 of 4]
is submitted in 600. The fallopian tube looks grossly unremarkable and representative sections are submitted in 6PP.

Specimen 7 is received fresh and is labeled "left uterine artery". The specimen consists of one portion of yellow-tan soft tissue measuring 2.0 x 1.2 x 0.3 cm. The specimen is submitted in toto and 7A.

SUMMARY OF SECTIONS: 55. multiole, representative sections

Dictator: '

Dictated by:

Clinical Information

-year-old with newly diagnosed SCCa cervix by colposcopy and biopsies. No infectious precautions, chemotherapy, radiation or biopsy.

Pre-Operative Diagnosis:

Post-Operative Diagnosis:

Operation: RAH/BSO

Specific questions to be answered:

Specimen:

1. Right aortic node
2. Left pelvic node
3. Right pelvic node
4. Portion of right parametrium
5. Portion of left parametrium
6. Uterus, tubes and ovaries, parametrium of upper vagina
7. Left uterine artery

*** End of report [] ***

End

Source: NCI Genomic Data Commons file 4533dd63-7ead-409b-a6a3-cdcedfee8eb0 (TCGA-EK-A2RM.3810E8FD-27A9-4E65-9BD2-BFA5594813B8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).